Somatic mutation profile of cancer-model specimen HCM-CSHL-0178-C25-85A (3D Organoid; aliquot HCM-CSHL-0178-C25-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0178-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.1 years (25,954 days).
Specimen HCM-CSHL-0178-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63f20e81-8978-444e-ac09-328bfe05bd66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0178-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0178-C25-10A-01D-A80U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fac78ceb-1174-43d8-9447-11c9fc9730ff

The open-access MAF lists 56 somatic variants for this specimen: 37 protein-altering or splice-affecting, 18 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 18, Nonsense Mutation 5, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 365/365 reads (100%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 140/307 reads (46%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 132/132 reads (100%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by mutect2, varscan2
- TP53 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 197/197 reads (100%) | hotspot (GDC flag); catalogued as rs397516435, CM941329, COSV52663748, COSV53125285, COSV53128268; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOL4 | c.827G>A p.R276K (on ENST00000352371 / NM_145660.2; = p.R273K on NM_030643.4) | Missense Mutation (SNP) | VAF 43/413 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as rs373896200; called by muse, mutect2, varscan2
- ARHGEF25 | c.1138C>T p.R380C | Missense Mutation (SNP) | VAF 175/428 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs79131014; called by muse, mutect2, varscan2
- CCDC136 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 104/190 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs770281978; called by muse, mutect2, varscan2
- CENPE | c.2608T>C p.Y870H | Missense Mutation (SNP) | VAF 97/98 reads (99%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99477181; called by muse, mutect2, varscan2
- DOK6 | c.755C>A p.T252N | Missense Mutation (SNP) | VAF 145/145 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV66932357; called by muse, mutect2, varscan2
- FLT4 | c.4060C>T p.R1354C | Missense Mutation (SNP) | VAF 182/380 reads (48%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.17); catalogued as rs761089407, COSV56098461; called by muse, mutect2, varscan2
- KCTD19 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 171/338 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs747458440; called by muse, mutect2, varscan2
- PLXND1 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 258/543 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs767303855, COSV60710688; called by muse, mutect2, varscan2
- POM121L12 | c.328C>T p.R110* | Nonsense Mutation (SNP) | VAF 280/612 reads (46%) | catalogued as rs1418866673, COSV68694385; called by muse, mutect2
- RNPEPL1 | c.1103C>T p.T368M | Missense Mutation (SNP) | VAF 186/596 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1404795524, COSV99549432; called by muse, mutect2, varscan2
- RYR2 | c.10258G>A p.V3420I | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as rs397516497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA5A | c.512C>T p.A171V | Missense Mutation (SNP) | VAF 67/366 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs746402219; called by muse, mutect2, varscan2
- SH2D3A | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754176794; called by muse, mutect2, varscan2
- SHE | c.829C>T p.R277W | Missense Mutation (SNP) | VAF 263/490 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs781170865, COSV59072167; called by muse, mutect2, varscan2
- TMBIM4 | c.214T>G p.L72V | Missense Mutation (SNP) | VAF 50/215 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.291); catalogued as COSV53970022; called by muse, mutect2, varscan2
- TRIO | c.7037G>A p.R2346Q | Missense Mutation (SNP) | VAF 238/462 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as rs761855758; called by muse, mutect2, varscan2
- ZIM3 | c.364G>A p.G122R | Missense Mutation (SNP) | VAF 201/366 reads (55%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as rs774474471, COSV54140013; called by muse, mutect2, varscan2
- CAPN15 | c.2953C>T p.L985F | Missense Mutation (SNP) | VAF 210/454 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPXM1 | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 169/169 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- DCLRE1A | c.3072G>C p.R1024S | Missense Mutation (SNP) | VAF 160/327 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- FAM189A2 | c.192A>C p.K64N | Missense Mutation (SNP) | VAF 48/398 reads (12%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- FAT3 | c.10015C>T p.P3339S | Missense Mutation (SNP) | VAF 175/352 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GLB1L3 | c.1506C>A p.C502* | Nonsense Mutation (SNP) | VAF 103/206 reads (50%) | called by muse, mutect2, varscan2
- KRTAP5-5 | c.362C>A p.S121Y | Missense Mutation (SNP) | VAF 40/111 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); called by muse, varscan2
- MAGEB10 | c.848C>A p.T283N | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NKX2-6 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PDS5A | c.1417C>G p.L473V | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- PLK2 | c.924G>T p.K308N | Missense Mutation (SNP) | VAF 158/370 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- POLR2J2 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 214/293 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PPEF1 | c.40_46+6del p.X14_splice | Splice Site (DEL) | VAF 24/179 reads (13%) | called by mutect2, pindel, varscan2
- PSMA7 | c.463G>T p.A155S | Missense Mutation (SNP) | VAF 145/363 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TNRC18 | c.3919A>C p.S1307R | Missense Mutation (SNP) | VAF 302/614 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- TP63 | c.1438C>T p.Q480* | Nonsense Mutation (SNP) | VAF 81/309 reads (26%) | called by muse, mutect2, varscan2
- ADGRL3 | c.4380G>A p.R1460= (on ENST00000506720 / NM_001322402.2; = p.R1349= on NM_015236.6) | Silent (SNP) | VAF 189/416 reads (45%) | called by muse, mutect2, varscan2
- CCDC168 | c.7836A>G p.K2612= | Silent (SNP) | VAF 204/652 reads (31%) | called by muse, mutect2, varscan2
- CIZ1 | c.2553C>T p.N851= | Silent (SNP) | VAF 226/492 reads (46%) | catalogued as rs376443811; called by muse, mutect2, varscan2
- CRISPLD1 | c.15G>A p.A5= | Silent (SNP) | VAF 113/264 reads (43%) | catalogued as rs766389465, COSV51547252; called by muse, mutect2, varscan2
- FCRL3 | c.63A>C p.P21= | Silent (SNP) | VAF 27/238 reads (11%) | called by muse, mutect2
- GNGT1 | c.204A>G p.K68= | Silent (SNP) | VAF 45/181 reads (25%) | catalogued as COSV50353507; called by muse, mutect2, varscan2
- HRNR | c.1470C>T p.G490= | Silent (SNP) | VAF 18/420 reads (4%) | called by muse, mutect2
- INTS13 | c.1653A>G p.Q551= | Silent (SNP) | VAF 234/454 reads (52%) | catalogued as rs1241935420, COSV53905103; called by muse, mutect2, varscan2
- IRGC | c.927C>T p.D309= | Silent (SNP) | VAF 221/482 reads (46%) | catalogued as rs199599515; called by muse, mutect2, varscan2
- MUC6 | c.6780C>T p.T2260= | Silent (SNP) | VAF 408/848 reads (48%) | catalogued as rs772349712, COSV70133944; called by muse, mutect2, varscan2
- NOS3 | c.2766G>A p.A922= | Silent (SNP) | VAF 303/598 reads (51%) | catalogued as rs1309870129, COSV99871949; called by muse, mutect2, varscan2
- OR4C46 | c.570C>T p.T190= | Silent (SNP) | VAF 39/311 reads (13%) | catalogued as rs140080586, COSV60220918; called by muse, mutect2, varscan2
- PXDN | c.1803G>T p.G601= | Silent (SNP) | VAF 165/344 reads (48%) | called by muse, mutect2, varscan2
- SLC26A4 | c.1299C>T p.I433= | Silent (SNP) | VAF 166/328 reads (51%) | catalogued as rs397516415; ClinVar: likely benign; called by muse, mutect2, varscan2
- ST14 | c.201G>A p.L67= | Silent (SNP) | VAF 196/413 reads (47%) | called by muse, mutect2, varscan2
- TNC | c.1725C>T p.D575= | Silent (SNP) | VAF 198/420 reads (47%) | catalogued as rs774414409; called by muse, varscan2
- TUBB2A | c.558C>T p.T186= | Silent (SNP) | VAF 37/327 reads (11%) | called by muse, mutect2, varscan2
- TUBB2B | c.558C>T p.T186= | Silent (SNP) | VAF 16/547 reads (3%) | called by muse, mutect2
- TMEM107 | c.*667A>G | 3'UTR (SNP) | VAF 183/183 reads (100%) | catalogued as rs772145329; called by muse, mutect2, varscan2
